Somatic mutation profile of tumor specimen TCGA-TK-A8OK-01A (aliquot TCGA-TK-A8OK-01A-22D-A364-08) from TCGA case TCGA-TK-A8OK, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 73.9 years (26,976 days).
Specimen TCGA-TK-A8OK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c1c38e8-fe68-46bf-b692-6f55546fceb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TK-A8OK-10A (Blood Derived Normal), aliquot TCGA-TK-A8OK-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd216de7-6a0d-4407-a7f5-71e8be89ec53

The open-access MAF lists 41 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 28, Silent 10, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51646097, COSV51647749; called by muse, mutect2
- ABCA13 | c.13570G>A p.A4524T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1163099421, COSV68948669; called by muse, mutect2, varscan2
- ADARB2 | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.494); catalogued as rs751820473, COSV67182195; called by muse, mutect2, varscan2
- APBB2 | c.1498G>A p.V500M (on ENST00000295974 / NM_001166050.2; = p.V501M on NM_004307.2) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs764979580, COSV55956397; called by muse, mutect2, varscan2
- ARID2 | c.3811T>G p.C1271G | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); catalogued as COSV100535123; called by muse, mutect2, varscan2
- ATP5PF | c.153A>C p.K51N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV99535345; called by muse, mutect2, varscan2
- C11orf24 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV100422440; called by muse, mutect2, varscan2
- CFHR1 | c.231G>T p.W77C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100258518, COSV57627818; called by muse, mutect2, varscan2
- CHD6 | c.881T>C p.I294T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1346376720, COSV100497536; called by muse, mutect2, varscan2
- DGLUCY | c.517A>C p.K173Q | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.172); catalogued as COSV99823853; called by muse, mutect2
- FAT3 | c.13408G>A p.E4470K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.458); catalogued as rs753317758, COSV53114577; called by muse, mutect2, varscan2
- GNAZ | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs369848697, COSV99321215; called by muse, mutect2, varscan2
- KCNS3 | c.284G>A p.C95Y | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100410881; called by muse, mutect2, varscan2
- LETMD1 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV100016319; called by muse, mutect2, varscan2
- LGI1 | c.1229T>C p.I410T | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV65058199; called by muse, mutect2, varscan2
- NCOA6 | c.4163G>A p.G1388E | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.462); catalogued as COSV100749863; called by muse, mutect2, varscan2
- NPS | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101219348; called by muse, mutect2, varscan2
- NTM | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs779837867, COSV100866773; called by muse, mutect2, varscan2
- OBSCN | c.4354G>T p.V1452L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV99470547; called by muse, mutect2, varscan2
- PCDHA4 | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs781816070, COSV100793032; called by muse, mutect2, varscan2
- PHF3 | c.4940A>G p.N1647S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as rs1253766312, COSV100012721; called by muse, mutect2, varscan2
- PKHD1 | c.638T>C p.L213P | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV100580656; called by muse, mutect2, varscan2
- PRG2 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as rs146228047, COSV61293131; called by muse, mutect2, varscan2
- RAET1E | c.253A>T p.S85C | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100593421; called by muse, mutect2, varscan2
- RSBN1 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs1353087249, COSV54731558; called by muse, mutect2, varscan2
- STAB2 | c.6029T>G p.L2010R | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV101185548; called by muse, mutect2, varscan2
- ZNF169 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.381); catalogued as rs779140159, COSV100566106; called by muse, mutect2, varscan2
- ZNF418 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.509); catalogued as rs770529656, COSV68675770; called by muse, mutect2, varscan2
- ARID4B | c.586-8_592del p.X196_splice | Splice Site (DEL) | VAF 11/61 reads (18%) | called by mutect2, pindel, varscan2
- DMXL1 | c.4079_4080del p.L1360Qfs*2 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel, varscan2
- SLC17A5 | c.402_411del p.G135Cfs*2 | Frame Shift Del (DEL) | VAF 30/149 reads (20%) | called by mutect2, pindel, varscan2
- AJAP1 | c.1125G>A p.S375= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs1326074109, COSV65451909; called by muse, mutect2, varscan2
- CCDC88C | c.1476C>T p.S492= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs368539046; called by muse, mutect2, varscan2
- FAM83H | c.1413C>T p.G471= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as rs1387843419, COSV101186903; called by muse, mutect2
- FLI1 | c.882C>T p.S294= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1448246958, COSV55643944; called by muse, mutect2
- H2AC14 | c.249C>T p.H83= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs756195484, COSV100297424; called by muse, mutect2, varscan2
- HMCN1 | c.6933C>T p.S2311= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs752504748, COSV54907402; called by muse, mutect2, varscan2
- PATJ | c.1092T>C p.Y364= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs200802733, COSV100332782; called by muse, mutect2, varscan2
- PCDHGA12 | c.717A>G p.A239= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs975772031, COSV99337050; called by muse, mutect2, varscan2
- PSD4 | c.3165G>A p.Q1055= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99830722; called by muse, mutect2, varscan2
- XBP1 | c.279T>G p.A93= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV99321449; called by muse, mutect2, varscan2
